CCDI case PBBJDE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/496ddc33-7c9d-479b-abfd-047528293e98

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Schwannoma, NOS: ICD-O-3 morphology code: 9560/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.5 years (3,818 days).

Biospecimens (3 samples)
- Sample 0DL4FN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DL4FP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DL4G1: Tissue type: Tumor; Specimen type: Solid Tissue.
